Surgical pathology report (de-identified scan), TCGA case TCGA-06-0174, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0174-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

PATHOLOGICAL DIAGNOSIS:

A, B. BRAIN, TEMPORAL, EXCISION: GLIOBLASTOMA MULTIFORME.

SEE COMMENT.

ADDENDUM DIAGNOSIS: MIB-1 PROLIFERATION: 9%.

Operation/Specimen: UPDATED REPORT - Right temporal brain tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

A. Received fresh, several fragments, 1.1 cm across in aggregate.
Soft, tannish-brown. In total #1 frozen tissue, #2 and 3 remainder
tissue.

INTRAOPERATIVE CONSULTATION: Brain, frozen section and smears:
Glioma. [REDACTED]

B.
SPECIMEN: Temporal brain tumor.
FIXATIVE: None.
GENERAL: Received on a Telfa pad is a 1.5 x 1.5 x 0.6 cm. portion
of pink-tan soft tissue.
SECTIONS: 1X-B - submitted in toto.
[REDACTED]

COMMENT: The specimen is cerebral cortex and white matter extensively infiltrated or effaced by a glial neoplastic proliferation with nuclear anaplastic features, frequent mitotic figures, prominent microvascular cellular proliferation, and small zones of necrosis, i.e a glioblastoma multiforme.

ADDENDUM REPORT

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, p53, and MIB-1 were performed on sections from block #2.

The GFAP demonstrates gliofibrilogenesis by the neoplastic cells. The neoplastic cells do not overexpress the p53 protein. With the MIB-1 a proliferation index of 9% is determined in the more active areas.
[REDACTED]

[page 2 of 2]
TCGA-06-0174

Source: NCI Genomic Data Commons file c4e554e9-113e-4380-a84b-7aa97b80465e (TCGA-06-0174.B93EB902-CEA8-4BF5-830B-DDBACEAB7444.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).